Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4920, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4920-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA - CJ - 4920

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (80% CLEAR CELLS, 20% EOSINOPHILIC CELLS), FUHRMAN'S NUCLEAR GRADE 2.

TUMOR CONFINED TO THE KIDNEY.

TUMOR MEASURES 5.5 CM IN MAXIMUM DIMENSION.

Ureteral, vascular and soft tissue margins of resection, free of tumor.

(B) RIGHT ADRENAL GLAND:

Adrenal cortical adenoma (2.9 cm in maximum dimension).

Margins of resection free of tumor.

(C) DISTAL ESOPHAGUS, PROXIMAL STOMACH:

SMOOTH MUSCLE NEOPLASM CONSISTENT WITH LEIOMYOMA. (SEE COMMENT)

TUMOR MEASURES 4.5 CM IN MAXIMUM DIMENSION.

Distal and proximal resection margins, free of tumor.

Focal ulceration of gastric mucosa, no tumor present.

Five lymph nodes, no tumor present.

COMMENT

The tumor in the peri esophageal and gastric adipose tissue demonstrates mature smooth muscle with microscopic focus of necrosis but without atypia or significant mitotic activity. The immunohistochemical stains demonstrate that the tumor is positive for desmin and negative for c-Kit, CD34 and S-100, supporting the diagnosis of leiomyoma.

GROSS DESCRIPTION

(A) LEFT KIDNEY - A left nephrectomy specimen with attached perinephric fat (overall 17.0 x 10.0 x 5.5 cm) with kidney (10.5 x 6.0 x 4.5 cm) and attached ureter (5.0 cm in length and 0.4 cm in diameter). Located in the upper pole is a well-circumscribed brown-yellow tumor (5.5 x 5.0 x 3.0 cm) with focal hemorrhage. The tumor approaches the renal capsule, but is confined to the kidney. The tumor is 0.4 cm from Gerota's fascia. No involvement of the renal sinus, renal vein, or perinephric fat is identified. The remaining renal parenchyma is unremarkable.

INK CODE: Black - Gerota's fascia.

SECTION CODE: A1, vascular and ureteral resection margin; A2-A7, tumor with adjacent renal parenchyma; A8, A9, tumor with renal capsule and inked Gerota's fascia; A10, grossly normal renal pelvis and renal sinus; A11, A12, normal renal parenchyma. (Note: Tumor sample is obtained for tumor bank and possible electron microscopy study.) [REDACTED]

(B) RIGHT ADRENAL GLAND - An adrenal gland with attached adipose tissue (4.5 x 2.5 x 2.0 cm). A well-circumscribed homogeneous brown-yellow tumor (2.9 x 2.4 x 1.9 cm) is present in the adrenal. Normal adrenal cortex is identified around the periphery of the tumor. No necrosis or hemorrhage is identified. Representative sections are submitted in cassette B1-B7. Tumor specimen was obtained for Tumor Bank and electron microscopy studies. [REDACTED]

(C) DISTAL ESOPHAGUS, PROXIMAL STOMACH - A specimen consisting of distal esophagus and proximal of stomach (8.0 x 6.0 x 5.0 cm overall). The distal esophagus measures 0.8 cm in length. Located in the serosal surface of the stomach, 0.5 cm from the GE junction is a well circumscribed encapsulated tumor (4.5 x 3.0 x 2.5 cm). The tumor is firmly attached to the gastric wall. The external surface of the tumor is smooth. Sectioning reveals the tumor parenchyma is light tan, firm and whorled. The center portion of the tumor is hemorrhagic with possible necrosis. The remaining gastric and esophageal mucosa is unremarkable.

INK CODE: Blue-external surface of the tumor.

SECTION CODE: C1, esophageal margin for frozen section examination; C2-C4, gastric margin for frozen section examination; C5, tumor representative section for frozen section examination; C6-C14, representative sections of the tumor (with gastric wall in C6-C7 and GE junction in C13-C14); C15, two possible lymph nodes; C16, three possible lymph nodes.

*FS/DX: MARGINS NEGATIVE (ESOPHAGEAL AND GASTRIC) SPINDLE CELL NEOPLASM FINAL DIAGNOSIS AFTER PERMANENT SECTIONS. [REDACTED]

CLINICAL HISTORY

Source: NCI Genomic Data Commons file 83a60d64-540a-4482-acfe-c9373ffa0831 (TCGA-CJ-4920.F6084EBA-0211-417B-8B52-B0F8FE16172F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).